Gene-level copy-number profile of tumor specimen ALCH-ADTC-TTP1-A from ALCHEMIST case ALCH-ADTC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.4 years (20,955 days).
Specimen ALCH-ADTC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c510d400-234f-41db-bfeb-56aec35ccc0f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADTC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/4a247725-6212-47cd-8899-269481aecbda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 396; copy number 1: 16,686; copy number 2: 38,107; copy number 3: 3,510; copy number 4: 87; copy number 5: 113; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 396 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 9 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–2): AL627309.3.
- chr2:232,343,116–232,536,667, 14 genes (within-gene range 0–1): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND.
- chr3:46,694,528–46,710,886, 1 gene: TMIE.
- chr3:46,835,111–47,009,704, 5 genes: MYL3, PTH1R, AC109583.3, CCDC12, NBEAL2.
- chr3:50,116,022–50,221,486, 5 genes (within-gene range 0–1): SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3.
- chr3:50,227,436–50,239,984, 2 genes (within-gene range 0–1): MIR5787, U73169.1.
- chr5:134,081,914–134,151,865, 2 genes (within-gene range 0–1): AC008608.1, TCF7.
- chr7:6,637,318–6,658,279, 1 gene: ZNF316.
- chr8:70,051,651–70,104,179, 3 genes: PRDM14, RNU1-101P, H2AZP2.
- chr10:117,542,445–117,549,546, 1 gene (within-gene range 0–2): EMX2.
- chr11:32,435,738–32,437,030, 3 genes (within-gene range 0–2): AL049692.6, AL049692.1, AL049692.5.
- chr14:24,052,009–24,125,242, 5 genes (within-gene range 0–1): CARMIL3, CPNE6, NRL, PCK2, DCAF11.
- chr14:104,137,150–104,180,894, 2 genes: AL359399.1, KIF26A.
- chr17:1,279,662–1,300,978, 1 gene: TRARG1.
- chr17:7,646,627–7,657,770, 1 gene: ATP1B2.
- chr17:36,936,785–36,944,612, 2 genes: LHX1, AC243773.1.
- chr18:64,041,555–64,423,601, 4 genes: LINC01924, RPL12P39, LINC00305, LINC01538.
- chr19:186,373–2,815,807, 166 genes (broad region; genes not listed).
- chr19:2,949,035–5,839,722, 126 genes (broad region; genes not listed).
- chr19:12,763,003–12,872,740, 4 genes (within-gene range 0–1): HOOK2, AC018761.3, MIR5684, JUNB.
- chr19:12,802,031–13,158,788, 35 genes: THSD8, RNASEH2A, RTBDN, AC020934.1, MAST1, MIR6794, DNASE2, AC020934.2, KLF1, GCDH, RPS6P25, SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1, DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42.
- chr20:62,513,909–62,551,526, 2 genes (within-gene range 0–2): AL499627.1, MIR1-1HG-AS1.
- chr20:62,554,306–62,554,376, 1 gene (within-gene range 0–2): MIR1-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 118 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:143,437,659–145,066,685, 113 genes, copy number 5 (broad region; genes not listed).
- chr21:44,107,373–44,210,114, 5 genes, copy number 6 (within-gene range 2–6): PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 13,830. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
